Somatic mutation profile of tumor specimen 0DTD3A from CCDI case PBCJFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.5 years (6,395 days).
Specimen 0DTD3A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89a298bd-2701-40dd-a57f-90863bff0c71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTD34 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e11b6c69-7524-487c-b16c-5b8a469b336e

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'UTR 3, Silent 3, Nonsense Mutation 2, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM47B | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 291/862 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61455846; called by muse, mutect2, varscan2
- KANSL1 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 26/510 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs765213873; ClinVar: likely benign; called by muse, mutect2
- POLR2B | c.2302C>T p.R768* | Nonsense Mutation (SNP) | VAF 142/432 reads (33%) | catalogued as rs755066139; called by muse, mutect2, varscan2
- PTCHD1 | c.1864C>T p.Q622* | Nonsense Mutation (SNP) | VAF 29/504 reads (6%) | catalogued as COSV65062245; called by muse, mutect2
- ARHGAP44 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 44/1006 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CDV3 | c.627-3T>A | Splice Region (SNP) | VAF 28/228 reads (12%) | called by muse, varscan2
- FAM104B | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2
- SPG21 | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 141/781 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- THADA | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 32/990 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- UACA | c.3281C>T p.A1094V | Missense Mutation (SNP) | VAF 38/775 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- LRRK1 | c.906C>T p.I302= | Silent (SNP) | VAF 60/686 reads (9%) | called by muse, mutect2
- PLCG2 | c.1593A>G p.K531= | Silent (SNP) | VAF 40/933 reads (4%) | called by muse, mutect2
- TRIM2 | c.129C>T p.C43= (on ENST00000437508; = p.C70= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 47/742 reads (6%) | catalogued as rs750120043, COSV100107477; ClinVar: uncertain significance; called by muse, mutect2
- CLEC4D | c.*68C>T | 3'UTR (SNP) | VAF 52/117 reads (44%) | catalogued as rs1215838651; called by muse, mutect2, varscan2
- GPX1 | c.*51G>T | 3'UTR (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2
- MUC19 | n.12027C>G | RNA (SNP) | VAF 34/529 reads (6%) | catalogued as rs1565830056; called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
